Somatic mutation profile of tumor specimen MP2PRT-PAVXRW-TMP1-A (aliquot MP2PRT-PAVXRW-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVXRW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,102 days).
Specimen MP2PRT-PAVXRW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d04397f-3abc-48b9-9f74-27b7b02bb9d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXRW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXRW-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd74f817-b15b-428c-86aa-123054f72216

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Frame Shift Del 3, Intron 2, Splice Site 2, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 86/532 reads (16%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 75/194 reads (39%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 55/303 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 55/277 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs768525028, COSV55743072; called by muse, mutect2, varscan2
- CCNH | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs375955863; called by muse, mutect2, varscan2
- COL3A1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs374476865; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CRHR1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 107/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1454028018, COSV53277065; called by muse, mutect2, varscan2
- ITM2A | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753512845; called by muse, mutect2, varscan2
- KCNH5 | c.2866C>A p.Q956K | Missense Mutation (SNP) | VAF 146/626 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs984614454; called by muse, mutect2, varscan2
- KIF16B | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 163/365 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs752435760, COSV61710618; called by muse, mutect2, varscan2
- LRFN5 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 170/660 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs143897378, COSV53277569; called by muse, mutect2, varscan2
- LTBP3 | c.3664C>T p.R1222C (on ENST00000301873 / NM_001130144.3; = p.R1175C on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV54215769; called by muse, mutect2, varscan2
- MAGEC1 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 264/891 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); catalogued as COSV53581658; called by muse, mutect2, varscan2
- MPDZ | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV59944049; called by muse, mutect2, varscan2
- NPDC1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 304/640 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs375207658; called by muse, mutect2, varscan2
- NYX | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 316/901 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs745419686, COSV100699428; called by muse, mutect2, varscan2
- POLD1 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771858429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOX6 | c.2086C>T p.R696C (on ENST00000528429 / NM_001145819.2; = p.R669C on NM_017508.3) | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419096036, COSV57056760; called by muse, mutect2
- UBL4A | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 148/567 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1385439085; called by muse, mutect2, varscan2
- ADH1B | c.994del p.V333Wfs*14 | Frame Shift Del (DEL) | VAF 75/321 reads (23%) | called by mutect2, pindel, varscan2
- ARSD | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 262/968 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMD | c.9835G>A p.A3279T | Missense Mutation (SNP) | VAF 167/558 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- FAM83B | c.2797G>A p.V933I | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRX1 | c.366_367dup p.F123Cfs*48 | Frame Shift Ins (INS) | VAF 211/539 reads (39%) | called by mutect2, pindel, varscan2
- MYH10 | c.3651+1G>T p.X1217_splice | Splice Site (SNP) | VAF 104/349 reads (30%) | called by muse, mutect2, varscan2
- MYH6 | c.1009T>G p.F337V | Missense Mutation (SNP) | VAF 54/680 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.278); called by muse, mutect2
- NPAS3 | c.1840C>T p.R614C (on ENST00000356141 / NM_001164749.2; = p.R582C on NM_022123.3) | Missense Mutation (SNP) | VAF 255/1148 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PYGO1 | c.571A>C p.N191H | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAGE1 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 131/500 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TAS2R3 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 21/413 reads (5%) | called by muse, mutect2
- TMTC2 | c.756del p.S254Pfs*75 | Frame Shift Del (DEL) | VAF 143/363 reads (39%) | called by mutect2, pindel, varscan2
- TRAPPC9 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- TRIM55 | c.1140_1141del p.Q381Gfs*40 | Frame Shift Del (DEL) | VAF 182/486 reads (37%) | called by pindel, varscan2
- AJAP1 | c.930C>T p.S310= | Silent (SNP) | VAF 137/296 reads (46%) | catalogued as rs971975405; called by muse, mutect2, varscan2
- COL4A2 | c.1464C>T p.G488= | Silent (SNP) | VAF 46/291 reads (16%) | catalogued as rs1269797589, COSV100847245; called by muse, mutect2, varscan2
- CSRNP3 | c.1521C>T p.S507= | Silent (SNP) | VAF 173/334 reads (52%) | catalogued as rs766392480, COSV100086430, COSV58787000; called by muse, mutect2, varscan2
- ESX1 | c.240C>T p.H80= | Silent (SNP) | VAF 233/752 reads (31%) | catalogued as COSV101006375; called by muse, varscan2
- FBN1 | c.4428C>T p.Y1476= | Silent (SNP) | VAF 129/323 reads (40%) | catalogued as rs767462642, CM161833, COSV57311734; ClinVar: likely benign; called by muse, mutect2, varscan2
- FEZF2 | c.774C>T p.G258= | Silent (SNP) | VAF 24/572 reads (4%) | catalogued as rs1480787558; called by muse, mutect2
- GPR137 | c.1245G>A p.P415= | Silent (SNP) | VAF 150/381 reads (39%) | catalogued as rs769279910, COSV100464601; called by muse, mutect2, varscan2
- KIAA1210 | c.2643C>G p.A881= | Silent (SNP) | VAF 70/776 reads (9%) | called by muse, mutect2
- OR4K15 | c.909G>A p.T303= (on ENST00000305051; = p.T279= on NM_001005486.1) | Silent (SNP) | VAF 312/641 reads (49%) | catalogued as rs746555319; called by muse, mutect2, varscan2
- SENP6 | c.982C>T p.L328= | Silent (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- SLC28A3 | c.1635G>A p.Q545= | Silent (SNP) | VAF 42/199 reads (21%) | called by muse, varscan2
- COA8 | c.386-5634G>A | Intron (SNP) | VAF 106/571 reads (19%) | catalogued as rs982793634; called by muse, mutect2, varscan2
- DLG2 | c.205-65598C>G | Intron (SNP) | VAF 61/358 reads (17%) | catalogued as COSV99716790; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139558 A>G | 5'Flank (SNP) | VAF 182/409 reads (44%) | called by muse, mutect2, varscan2
